Gene-level copy-number profile of tumor specimen TCGA-ZF-A9R4-01A from TCGA case TCGA-ZF-A9R4, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 83.2 years (30,398 days).
Specimen TCGA-ZF-A9R4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9d17a1e6-30c8-484c-9762-48f72c335916.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-A9R4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e431d1d-2273-4134-ad1f-0836e6ee5ff5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 51; copy number 2: 8,785; copy number 3: 25,077; copy number 4: 17,537; copy number 5: 4,530; copy number 6: 1,788; copy number 7: 295; copy number 8: 654; copy number 9: 171; copy number 10: 376; copy number 12: 281; copy number 13: 100; copy number 15: 162; copy number 17: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-A9R4-01A-11D-A38F-01): tumor purity 0.91, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,013 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,344,850–56,155,224, 465 genes, copy number 7–15 (broad region; genes not listed).
- chr1:56,207,567–56,208,456, 1 gene, copy number 7: RPSAP20.
- chr1:56,823,679–58,700,077, 20 genes, copy number 9: AL360295.1, C8A, C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1.
- chr1:150,548,562–161,309,968, 560 genes, copy number 10–15 (broad region; genes not listed).
- chr1:161,735,808–169,460,669, 157 genes, copy number 8 (broad region; genes not listed).
- chr1:182,641,816–189,876,160, 107 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr1:192,158,462–201,028,792, 108 genes, copy number 8 (broad region; genes not listed).
- chr3:11,745–33,869,707, 458 genes, copy number 7–8 (broad region; genes not listed).
- chr3:34,152,979–34,157,297, 1 gene, copy number 8: AC123023.2.
- chr5:52,282,567–53,414,260, 17 genes, copy number 9–10: RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1.
- chr17:4,481,966–6,831,761, 104 genes, copy number 9–17 (within-gene range 6–17) (broad region; genes not listed).
- chr17:8,878,911–9,645,325, 15 genes, copy number 13: PIK3R5, AC002091.2, AC002091.1, NTN1, AC005695.1, AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
